Somatic mutation profile of tumor specimen MP2PRT-PANUAU-TMP1-A (aliquot MP2PRT-PANUAU-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANUAU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (658 days).
Specimen MP2PRT-PANUAU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab7b6e1f-9d7d-44c0-ad0c-dad30965fd53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUAU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUAU-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f8ad3e8-fda7-41a2-b8e4-5a81a7ceb817

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SERP1 | c.58_59insCCCC p.Q20Pfs*51 | Frame Shift Ins (INS) | VAF 114/461 reads (25%) | called by pindel, varscan2
- MROH1 | c.3033C>T p.D1011= | Silent (SNP) | VAF 224/557 reads (40%) | catalogued as rs1489083656; called by muse, mutect2, varscan2
- SMTNL2 | c.1161C>T p.C387= (on ENST00000389313 / NM_001114974.2; = p.C243= on NM_198501.3) | Silent (SNP) | VAF 143/455 reads (31%) | catalogued as rs534678064, COSV100130704; called by muse, mutect2, varscan2
- SPAG5 | c.2712T>C p.S904= | Silent (SNP) | VAF 42/255 reads (16%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins TC | 3'Flank (INS) | VAF 44/210 reads (21%) | called by mutect2, pindel, varscan2
